Somatic mutation profile of tumor specimen TCGA-GN-A4U4-06A (aliquot TCGA-GN-A4U4-06A-11D-A32N-08) from TCGA case TCGA-GN-A4U4, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 73.4 years (26,803 days).
Specimen TCGA-GN-A4U4-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 948d2a71-2ec5-44b9-8893-7ec0a02cfd54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GN-A4U4-10B (Blood Derived Normal), aliquot TCGA-GN-A4U4-10B-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9b5788b-b115-4771-bd56-cbd44b5a7dcf

The open-access MAF lists 820 somatic variants for this specimen: 545 protein-altering or splice-affecting, 256 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 499, Silent 256, Nonsense Mutation 34, Intron 8, RNA 6, Splice Site 5, Frame Shift Del 5, 3'UTR 3, 3'Flank 2, Splice Region 1, Frame Shift Ins 1.

Variants (750 of 820; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.1891G>A p.G631R | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as rs886044730, COSV100933334; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IKZF1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs759124417, COSV58782650, COSV58783750; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 162/299 reads (54%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RAF1 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 37/103 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs80338796, CM073301, COSV52574378, COSV52579821; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RPL5 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 27/75 reads (36%) | catalogued as rs1057520746, CM108640, COSV59874085; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1876A>T p.N626Y | Missense Mutation (SNP) | VAF 28/96 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59206442, COSV59212920, COSV59229378; called by muse, mutect2, varscan2
- SRD5A2 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1553323488, CM108679, COSV99252684; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AATK | c.3257C>T p.P1086L (on ENST00000326724 / NM_001080395.3; = p.P983L on NM_004920.2) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs777088304, COSV100353396; called by muse, varscan2
- AATK | c.3256C>T p.P1086S (on ENST00000326724 / NM_001080395.3; = p.P983S on NM_004920.2) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100353397; called by muse, mutect2, varscan2
- ABCA13 | c.12760C>T p.P4254S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68948608; called by muse, mutect2, varscan2
- ABCD2 | c.1958G>A p.G653E | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.045); catalogued as COSV58050066, COSV58051493; called by muse, mutect2, varscan2
- ABCG1 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 69/208 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs780891600, COSV59202084; called by muse, mutect2, varscan2
- ABLIM1 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 69/169 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99522872; called by muse, mutect2, varscan2
- ABLIM2 | c.1379A>G p.K460R (on ENST00000341937 / NM_001130084.2; = p.K409R on NM_032432.5) | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99590795; called by muse, mutect2, varscan2
- AC011448.1 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 89/226 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); catalogued as rs760705049, COSV99365314; called by muse, mutect2, varscan2
- ACAN | c.2962G>A p.G988R | Missense Mutation (SNP) | VAF 104/318 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100719441; called by muse, varscan2
- ADIPOQ | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868567951, COSV57860045; called by muse, mutect2, varscan2
- AEBP1 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as COSV99789182; called by muse, mutect2, varscan2
- AKAP10 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99855629; called by muse, mutect2, varscan2
- ALDH16A1 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99513302; called by muse, mutect2, varscan2
- ALK | c.2000G>A p.G667E | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66578303; called by muse, mutect2, varscan2
- ALOXE3 | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 64/192 reads (33%) | catalogued as COSV59075200; called by muse, mutect2, varscan2
- ALS2CL | c.2057G>A p.G686E | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs765835852, COSV59672729; called by muse, mutect2, varscan2
- AMER1 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 51/61 reads (84%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV100367176; called by muse, mutect2, varscan2
- AMPD3 | c.1345G>A p.E449K (on ENST00000396553 / NM_001025389.2; = p.E458K on NM_000480.3) | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101158292; called by muse, mutect2, varscan2
- ANAPC2 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV100119263; called by muse, mutect2, varscan2
- ANK3 | c.10727C>T p.P3576L | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.154); catalogued as COSV99782942; called by muse, mutect2, varscan2
- ANK3 | c.8602G>A p.E2868K | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as rs866590077, COSV55082047; called by muse, mutect2, varscan2
- ANKRD30A | c.1711C>T p.L571F (on ENST00000611781; = p.L515F on NM_052997.2) | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100654603; called by muse, mutect2
- ANO2 | c.1144C>T p.L382F (on ENST00000356134 / NM_001278597.3; = p.L386F on NM_001278596.3) | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.432); catalogued as COSV100500159, COSV59024171; called by muse, mutect2, varscan2
- ANO4 | c.709C>T p.P237S (on ENST00000392977 / NM_001286615.2; = p.P202S on NM_178826.4) | Missense Mutation (SNP) | VAF 79/221 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1008739959, COSV100154073; called by muse, mutect2, varscan2
- ANO4 | c.2516C>T p.S839F (on ENST00000392977 / NM_001286615.2; = p.S804F on NM_178826.4) | Missense Mutation (SNP) | VAF 82/207 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100154074; called by muse, mutect2, varscan2
- APOBEC3B | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.465); catalogued as COSV100213883; called by muse, mutect2, varscan2
- AREG | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 26/76 reads (34%) | catalogued as rs1283640826; called by muse, mutect2, varscan2
- ARHGEF5 | c.2663C>T p.P888L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.326); catalogued as rs1215683394, COSV50225986; called by mutect2, varscan2
- ARID2 | c.610C>T p.L204F | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100537199; called by muse, mutect2, varscan2
- ARID5A | c.847G>A p.G283R | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV100673677; called by muse, mutect2, varscan2
- ASB18 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as COSV101293648; called by muse, mutect2, varscan2
- ASIC5 | c.1243C>T p.L415F | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.261); catalogued as rs959962823, COSV73332940; called by muse, mutect2, varscan2
- ASTN1 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs760442147, COSV56061330; called by muse, mutect2, varscan2
- ASTN1 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.022); catalogued as COSV99921597; called by muse, mutect2, varscan2
- ASZ1 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.18); catalogued as COSV52912224; called by muse, mutect2, varscan2
- ATP11A | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as COSV99370258; called by muse, mutect2, varscan2
- ATP2B2 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100660605; called by muse, mutect2, varscan2
- ATP2B4 | c.3338C>T p.S1113F | Missense Mutation (SNP) | VAF 97/186 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV58176706; called by muse, mutect2, varscan2
- ATP8A1 | c.2486C>T p.S829F | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs267600160, COSV52529896; called by muse, mutect2, varscan2
- AZGP1 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); catalogued as COSV99448291; called by muse, mutect2, varscan2
- BCL11A | c.2265G>A p.M755I (on ENST00000335712 / NM_001365609.1; = p.M789I on NM_022893.4) | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100186738; called by muse, mutect2, varscan2
- BCL3 | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV99378383; called by muse, mutect2, varscan2
- BMP4 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55415144; called by muse, mutect2, varscan2
- BRINP2 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV64175044; called by muse, mutect2, varscan2
- BRWD3 | c.1471T>A p.F491I | Missense Mutation (SNP) | VAF 40/55 reads (73%) | SIFT tolerated (0.48); PolyPhen benign (0.124); catalogued as COSV100956649; called by muse, mutect2, varscan2
- C12orf50 | c.819G>A p.M273I | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as COSV100072565; called by muse, mutect2, varscan2
- C12orf56 | c.1174G>A p.D392N (on ENST00000543942 / NM_001170633.2; = p.D232N on NM_001099676.3) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.801); catalogued as rs866405788, COSV100399092; called by muse, mutect2, varscan2
- C14orf39 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.856); catalogued as rs752656015, COSV100408190; called by muse, mutect2, varscan2
- C1R | c.1798G>A p.D600N (on ENST00000536053 / NM_001354346.2; = p.D586N on NM_001733.7) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.051); catalogued as rs757372137, COSV101605639; called by muse, mutect2, varscan2
- C1RL | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as COSV99865034; called by muse, mutect2, varscan2
- C1orf87 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as COSV100967295; called by muse, mutect2, varscan2
- C6 | c.1147A>G p.S383G | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as COSV99667968; called by muse, mutect2, varscan2
- CACNA1S | c.532G>A p.G178R | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as rs1194119384, COSV100755455; called by muse, mutect2, varscan2
- CADPS | c.3266G>A p.G1089E | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as COSV99341492; called by muse, mutect2, varscan2
- CADPS2 | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as COSV100466632; called by muse, mutect2, varscan2
- CAPN1 | c.1951C>T p.L651F | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99658969; called by muse, mutect2, varscan2
- CARD11 | c.2024G>A p.S675N | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100829372; called by muse, mutect2, varscan2
- CASR | c.2507C>T p.S836F (on ENST00000490131; = p.S913F on NM_000388.4) | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs751273631, COSV99949587; called by muse, mutect2, varscan2
- CATSPERB | c.2133G>A p.W711* | Nonsense Mutation (SNP) | VAF 54/155 reads (35%) | catalogued as COSV56434562; called by muse, mutect2, varscan2
- CBX2 | c.1456T>G p.S486A | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV99491067; called by muse, mutect2
- CCDC136 | c.2519C>T p.P840L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as COSV99923386; called by muse, mutect2, varscan2
- CCDC57 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.211); catalogued as COSV101052137; called by muse, mutect2
- CCNA1 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV55220223; called by muse, mutect2, varscan2
- CCNL1 | c.675G>A p.W225* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99904667; called by muse, mutect2, varscan2
- CCNL1 | c.675-1G>A p.X225_splice | Splice Site (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99904668; called by muse, mutect2, varscan2
- CCNP | c.230A>G p.E77G | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99695954; called by muse, mutect2, varscan2
- CCR1 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.358); catalogued as rs1172370267, COSV99946838; called by muse, mutect2, varscan2
- CD101 | c.2836C>T p.P946S | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV56721918; called by muse, mutect2, varscan2
- CDCA3 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.046); catalogued as COSV99977162; called by muse, mutect2, varscan2
- CDH23 | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV54958657; called by muse, mutect2, varscan2
- CEACAM20 | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100387013; called by muse, mutect2, varscan2
- CECR2 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52847961; called by muse, mutect2, varscan2
- CENPN | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs528102999, COSV55141477; called by muse, mutect2, varscan2
- CEP290 | c.4541A>T p.E1514V | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.203); catalogued as COSV100470170; called by muse, mutect2, varscan2
- CFAP44 | c.2719G>A p.G907R | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV99870494; called by muse, mutect2, varscan2
- CFAP94 | c.690C>A p.F230L (on ENST00000320267 / NM_001352064.2; = p.F236L on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as rs1483034971, COSV57233418; called by muse, mutect2, varscan2
- CHD4 | c.3151G>A p.E1051K (on ENST00000357008 / NM_001363606.2; = p.E1064K on NM_001273.5) | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV100539490; called by muse, mutect2, varscan2
- CHL1 | c.1804G>A p.D602N (on ENST00000397491 / NM_001253387.1; = p.D618N on NM_006614.4) | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as rs186218301; called by muse, mutect2, varscan2
- CHRDL1 | c.901C>T p.P301S (on ENST00000372045; = p.P307S on NM_145234.4) | Missense Mutation (SNP) | VAF 93/128 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); catalogued as COSV99488839; called by muse, mutect2, varscan2
- CLDN10 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV100176306; called by muse, mutect2, varscan2
- CLEC18B | c.923G>A p.G308E | Missense Mutation (SNP) | VAF 23/362 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as rs1203060496; called by muse, mutect2
- CNMD | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.06); catalogued as rs1156509353, COSV100139753; called by muse, mutect2, varscan2
- CNOT2 | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.205); catalogued as COSV99973280; called by muse, mutect2, varscan2
- CNR2 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs757744382, COSV65693384; called by muse, mutect2
- CNTN1 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); catalogued as COSV100752008; called by muse, mutect2, varscan2
- COL3A1 | c.637-1G>A p.X213_splice | Splice Site (SNP) | VAF 12/28 reads (43%) | catalogued as COSV58586999; called by mutect2, varscan2
- COL4A1 | c.1067G>A p.G356E | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101011641; called by muse, mutect2, varscan2
- COL4A4 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100307970; called by muse, mutect2, varscan2
- COL5A2 | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.933); catalogued as COSV100880949; called by muse, mutect2, varscan2
- COL5A2 | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.066); catalogued as COSV66415122; called by muse, mutect2, varscan2
- COL9A3 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV100102532; called by muse, mutect2, varscan2
- COMT | c.763G>T p.D255Y | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99258969; called by muse, mutect2, varscan2
- COX18 | c.929C>T p.T310I | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV99887245; called by muse, mutect2, varscan2
- CPAMD8 | c.2113C>T p.P705S (on ENST00000651564; = p.P658S on NM_015692.5) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.05); catalogued as COSV99359915; called by muse, mutect2, varscan2
- CRHBP | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 71/217 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99169550; called by muse, mutect2, varscan2
- CSMD1 | c.1439C>T p.S480L (on ENST00000520002; = p.S479L on NM_033225.6) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.227); catalogued as rs370398160; called by muse, mutect2, varscan2
- CSMD3 | c.3748G>A p.G1250R (on ENST00000297405 / NM_001363185.1; = p.G1146R on NM_052900.3) | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99851223; called by muse, mutect2, varscan2
- CSTF2T | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 106/290 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs770308185, COSV100484346; called by muse, mutect2, varscan2
- CTNNA3 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 73/221 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV65602250; called by muse, mutect2, varscan2
- CXXC1 | c.1627A>G p.K543E | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99497459; called by muse, mutect2, varscan2
- CYP2C9 | c.1329G>A p.M443I | Missense Mutation (SNP) | VAF 82/225 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV99583348; called by muse, mutect2, varscan2
- CYP4B1 | c.1116G>C p.E372D | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775948977, COSV54723218; called by muse, mutect2, varscan2
- DCC | c.2053G>A p.G685R | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59098011; called by muse, mutect2, varscan2
- DDC | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 98/289 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100779837; called by muse, mutect2, varscan2
- DDX21 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV100826560; called by muse, mutect2, varscan2
- DDX60 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101190761; called by muse, mutect2, varscan2
- DDX60L | c.1589C>T p.S530L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs761894325, COSV52716696; called by muse, mutect2
- DENND2A | c.2777G>A p.R926K | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV99327189; called by muse, mutect2, varscan2
- DENND2C | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs368021056, COSV101283898; called by muse, mutect2, varscan2
- DENND5B | c.3754C>T p.R1252* | Nonsense Mutation (SNP) | VAF 25/67 reads (37%) | catalogued as rs981331087, COSV60905681; called by muse, mutect2, varscan2
- DGKZ | c.2276C>T p.A759V (on ENST00000454345 / NM_001105540.2; = p.A571V on NM_003646.4) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.627); catalogued as COSV100552124; called by muse, mutect2, varscan2
- DHX36 | c.1903C>T p.P635S | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.258); catalogued as COSV100273341; called by muse, mutect2, varscan2
- DIAPH3 | c.1387G>A p.E463K (on ENST00000400324 / NM_001042517.2; = p.E200K on NM_030932.3) | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1419808515, COSV57374197, COSV99934687; called by muse, mutect2, varscan2
- DICER1 | c.5183C>T p.S1728F | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762801582, COSV100602657; called by muse, mutect2, varscan2
- DLST | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as rs771125023, COSV99472206; called by muse, mutect2, varscan2
- DMBT1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780912281, COSV57532698; called by muse, mutect2, varscan2
- DMXL1 | c.5720C>T p.S1907F | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as rs1287469824, COSV100225234; called by muse, mutect2, varscan2
- DNAAF5 | c.1978C>T p.P660S | Missense Mutation (SNP) | VAF 69/191 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV99860412; called by muse, varscan2
- DNAH10 | c.6966G>A p.W2322* (on ENST00000409039; = p.W2261* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 21/63 reads (33%) | catalogued as COSV68994176; called by muse, mutect2, varscan2
- DNAH11 | c.2114C>T p.P705L | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as rs1221969023, COSV100181384; called by muse, mutect2, varscan2
- DNAH11 | c.8570G>A p.G2857E | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100181385; called by muse, mutect2, varscan2
- DNAH5 | c.9721-1G>A p.X3241_splice | Splice Site (SNP) | VAF 90/230 reads (39%) | catalogued as COSV54219005; called by muse, mutect2, varscan2
- DNAH7 | c.10960A>T p.T3654S | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as COSV100418135; called by muse, mutect2, varscan2
- DOCK3 | c.5098G>A p.D1700N | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); catalogued as COSV99815863; called by muse, mutect2, varscan2
- DPYD | c.1862G>A p.W621* | Nonsense Mutation (SNP) | VAF 59/151 reads (39%) | catalogued as rs1182668539, COSV100929629; called by muse, mutect2, varscan2
- DPYS | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs765884757, COSV60906455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DRGX | c.344G>A p.R115K | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.197); catalogued as COSV100938407; called by muse, mutect2, varscan2
- DSC1 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99938407; called by muse, mutect2, varscan2
- DSC1 | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs267605152, COSV57142434; called by muse, mutect2, varscan2
- DSC1 | c.266G>A p.R89K | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57141945; called by muse, mutect2, varscan2
- DSG3 | c.2825C>T p.S942F | Missense Mutation (SNP) | VAF 73/180 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs141527621, COSV57126777; called by muse, mutect2, varscan2
- DSG4 | c.2377G>A p.E793K | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs200463781, COSV100356530; called by muse, mutect2, varscan2
- DST | c.13147T>A p.S4383T (on ENST00000361203 / NM_001374722.1; = p.S1971T on NM_015548.5) | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.25); PolyPhen benign (0.143); catalogued as COSV99760925; called by muse, mutect2, varscan2
- DUXA | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs866701297, COSV73729502; called by muse, mutect2, varscan2
- E2F7 | c.2584C>T p.P862S | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100524072; called by muse, mutect2, varscan2
- EBNA1BP2 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as COSV99356126; called by muse, mutect2, varscan2
- EIF1AY | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV100797194; called by muse, mutect2, varscan2
- ELL2 | c.1741C>T p.P581S | Missense Mutation (SNP) | VAF 114/293 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV99427988; called by muse, mutect2, varscan2
- ENDOD1 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0.085); catalogued as COSV99566909; called by muse, mutect2, varscan2
- ENGASE | c.1916C>T p.P639L | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100286009; called by muse, mutect2, varscan2
- ENOX1 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1317898686, COSV99817564; called by muse, mutect2, varscan2
- ENPEP | c.1837G>A p.G613R | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.291); catalogued as COSV54451938, COSV99488279; called by muse, mutect2, varscan2
- ENTHD1 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV100288225, COSV100289248; called by muse, mutect2, varscan2
- EPHA1 | c.2344G>A p.E782K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs1454804041, COSV51969779; called by muse, mutect2, varscan2
- EPHA4 | c.2317G>A p.D773N | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.625); catalogued as COSV56033890; called by muse, mutect2, varscan2
- EPHA6 | c.1600C>T p.Q534* | Nonsense Mutation (SNP) | VAF 48/128 reads (38%) | catalogued as COSV101066075; called by muse, mutect2, varscan2
- EPHA6 | c.2489C>T p.S830F (on ENST00000389672 / NM_001080448.3; = p.S222F on NM_173655.4) | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated, low confidence (0.55); PolyPhen possibly damaging (0.691); catalogued as COSV67559197; called by muse, mutect2, varscan2
- EPHB1 | c.922T>C p.Y308H | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.534); catalogued as COSV101214738; called by muse, mutect2, varscan2
- EPHB2 | c.1831G>A p.E611K (on ENST00000400191 / NM_001309193.2; = p.E612K on NM_004442.7) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as rs1425174126, COSV65861674; called by muse, mutect2, varscan2
- ERBB4 | c.2131C>T p.R711C | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs267599191, COSV53505317; called by muse, mutect2, varscan2
- ERC2 | c.240G>A p.M80I | Missense Mutation (SNP) | VAF 93/209 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.38); catalogued as COSV99891626; called by muse, mutect2, varscan2
- ERCC6 | c.3656G>A p.G1219E | Missense Mutation (SNP) | VAF 159/458 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100876337; called by muse, mutect2, varscan2
- ERICH3 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 74/206 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs1040060945, COSV100446079, COSV58612488; called by muse, mutect2
- EYA1 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as rs780203392, COSV58160409; called by muse, mutect2, varscan2
- EZR | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 18/29 reads (62%) | catalogued as COSV100455159; called by muse, mutect2, varscan2
- F13B | c.1481C>T p.P494L | Missense Mutation (SNP) | VAF 71/132 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100803533; called by muse, mutect2, varscan2
- FAM120A | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV52904799, COSV99466819; called by muse, mutect2, varscan2
- FAM135B | c.3089T>C p.V1030A | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs1473226559, COSV99428546; called by muse, mutect2, varscan2
- FAM135B | c.2224G>A p.G742S | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs754183792, COSV52724198, COSV52734285; called by muse, mutect2, varscan2
- FAM160B2 | c.1913C>T p.P638L | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs769252990, COSV99249331; called by muse, mutect2, varscan2
- FAM193A | c.3389C>T p.P1130L | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as rs761235700, COSV100219715; called by muse, mutect2, varscan2
- FAM81B | c.154A>G p.T52A | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.055); catalogued as rs373398709; called by muse, mutect2, varscan2
- FARP2 | c.1600G>A p.D534N | Missense Mutation (SNP) | VAF 81/142 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1412629904, COSV99885764; called by muse, mutect2, varscan2
- FAT4 | c.10253G>A p.G3418E | Missense Mutation (SNP) | VAF 96/237 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100630558, COSV100630656; called by muse, mutect2, varscan2
- FAT4 | c.14063C>T p.S4688F | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV58690701; called by muse, mutect2, varscan2
- FBH1 | c.1018G>A p.G340R (on ENST00000362091 / NM_178150.3; = p.G391R on NM_032807.4) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as rs761484939, COSV100758986; called by muse, mutect2, varscan2
- FBH1 | c.1019G>A p.G340E (on ENST00000362091 / NM_178150.3; = p.G391E on NM_032807.4) | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV100758987; called by muse, mutect2, varscan2
- FBXO40 | c.1466C>T p.P489L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV100573349, COSV57525521; called by muse, mutect2, varscan2
- FCN1 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 149/386 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as rs866896940, COSV100878994; called by muse, mutect2, varscan2
- FCRL2 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 70/132 reads (53%) | catalogued as COSV63833251, COSV63835513; called by muse, mutect2, varscan2
- FGA | c.1919C>T p.P640L | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV100120837; called by muse, mutect2, varscan2
- FGD6 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.001); catalogued as rs751217978, COSV59690883; called by muse, mutect2, varscan2
- FGFBP2 | c.621G>A p.W207* | Nonsense Mutation (SNP) | VAF 43/103 reads (42%) | catalogued as COSV52587878; called by muse, mutect2, varscan2
- FLG | c.10246G>A p.E3416K | Missense Mutation (SNP) | VAF 428/770 reads (56%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as rs140368354; called by muse, mutect2, varscan2
- FLG | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 69/277 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64249858; called by muse, mutect2, varscan2
- FLNA | c.7406C>T p.P2469L (on ENST00000369850 / NM_001110556.2; = p.P2461L on NM_001456.3) | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1557175381, COSV100775382; called by muse, mutect2, varscan2
- FLNA | c.7405C>T p.P2469S (on ENST00000369850 / NM_001110556.2; = p.P2461S on NM_001456.3) | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61038813; called by muse, mutect2, varscan2
- FLRT1 | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55358882; called by muse, mutect2, varscan2
- FLT3 | c.2528T>C p.V843A | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV54043544; called by muse, mutect2, varscan2
- FLT4 | c.3239G>A p.W1080* | Nonsense Mutation (SNP) | VAF 44/118 reads (37%) | catalogued as COSV56108833; called by muse, mutect2, varscan2
- FMNL3 | c.2800G>A p.A934T | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.038); catalogued as COSV53305351, COSV99527219; called by muse, mutect2, varscan2
- FN1 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778879562, COSV100118539; called by muse, mutect2, varscan2
- FOSL2 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV99268586; called by muse, mutect2, varscan2
- FRMD8 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58213113; called by muse, mutect2
- GATA3 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100651296; called by muse, mutect2, varscan2
- GATA5 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV99436158; called by muse, mutect2, varscan2
- GCM2 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 65/288 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as COSV101069653; called by muse, mutect2, varscan2
- GFRAL | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV100476171; called by muse, mutect2, varscan2
- GLI3 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.027); catalogued as rs769650527, COSV101230145; called by muse, mutect2, varscan2
- GLRB | c.344G>A p.R115K | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100030232; called by muse, mutect2, varscan2
- GLYATL1 | c.862G>A p.E288K (on ENST00000317391 / NM_001354699.1; = p.E319K on NM_080661.4) | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.099); catalogued as COSV100265603; called by muse, mutect2, varscan2
- GNA15 | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 82/209 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99505494; called by muse, mutect2, varscan2
- GPLD1 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 97/191 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.584); catalogued as COSV100015640; called by muse, mutect2, varscan2
- GPR179 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1265115446; called by muse, mutect2, varscan2
- GPR4 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV59916047; called by muse, mutect2, varscan2
- GREB1 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99304021; called by muse, mutect2, varscan2
- GRIK5 | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs868980490, COSV53488430; called by muse, mutect2, varscan2
- GRIN2C | c.1882A>G p.M628V | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99501618; called by muse, mutect2, varscan2
- GRK2 | c.369C>T p.P123= | Splice Region (SNP) | VAF 24/97 reads (25%) | catalogued as COSV100419788; called by muse, mutect2, varscan2
- GRM5 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 74/100 reads (74%) | SIFT deleterious (0.05); PolyPhen benign (0.133); catalogued as COSV59601513, COSV59603490; called by muse, mutect2, varscan2
- GSDMC | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs759624672, COSV52696137; called by muse, mutect2, varscan2
- GUCY2D | c.1577G>A p.G526E | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV99644376; called by muse, mutect2, varscan2
- HECTD4 | c.3172C>A p.P1058T | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV100296247, COSV61178184; called by muse, mutect2, varscan2
- HELZ | c.5095C>T p.P1699S | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.071); catalogued as COSV100699124; called by muse, mutect2, varscan2
- HGFAC | c.760G>A p.G254S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs1252294124, COSV100123426; called by muse, mutect2, varscan2
- HIVEP1 | c.808C>T p.Q270* | Nonsense Mutation (SNP) | VAF 181/288 reads (63%) | catalogued as COSV101045885; called by muse, mutect2, varscan2
- HLA-A | c.449T>C p.L150P | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100954429, COSV65138189; called by muse, mutect2, varscan2
- HMGCLL1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as COSV51441581; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.528); catalogued as COSV100079911, COSV57134093; called by muse, mutect2, varscan2
- HOXB2 | c.554G>T p.R185M | Missense Mutation (SNP) | VAF 77/170 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100344853; called by muse, mutect2, varscan2
- HOXD10 | c.366A>T p.K122N | Missense Mutation (SNP) | VAF 89/222 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.234); catalogued as COSV99983073; called by muse, mutect2, varscan2
- ICAM5 | c.1067G>A p.G356E | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55749793, COSV99703593; called by muse, mutect2, varscan2
- IDO2 | c.1150G>A p.G384R (on ENST00000389060; = p.G397R on NM_194294.2) | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1406478105, COSV100585016; called by muse, mutect2, varscan2
- IFT57 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs149049643, COSV52711075; called by muse, mutect2, varscan2
- IGSF1 | c.2593G>A p.E865K | Missense Mutation (SNP) | VAF 116/156 reads (74%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV100812446; called by muse, mutect2, varscan2
- IGSF10 | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.335); catalogued as rs1247321142, COSV99199924; called by muse, mutect2, varscan2
- IHH | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.089); catalogued as COSV99838829; called by muse, mutect2, varscan2
- ILDR1 | c.1267G>A p.D423N (on ENST00000344209 / NM_001199799.2; = p.D379N on NM_175924.4) | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.46); catalogued as rs1172585670, COSV56553190; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IMPG1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 51/79 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV100886767; called by muse, mutect2, varscan2
- INMT | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV99185187; called by muse, mutect2, varscan2
- INPP4B | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99527303; called by muse, mutect2, varscan2
- IQCA1 | c.1778G>A p.G593E | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760740528, COSV99610561; called by muse, mutect2, varscan2
- IRGC | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1229567997, COSV99746628; called by muse, mutect2, varscan2
- ITGA4 | c.671C>G p.S224C | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99276419; called by muse, mutect2, varscan2
- ITIH1 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV56256625; called by muse, mutect2, varscan2
- ITM2A | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as COSV100964486, COSV64810604; called by muse, mutect2, varscan2
- JAG2 | c.3190G>A p.A1064T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100078914; called by muse, mutect2
- KCNB2 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 57/220 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV73049920, COSV73053662; called by muse, mutect2, varscan2
- KCND2 | c.1862G>A p.G621E | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.055); catalogued as COSV58579593; called by muse, mutect2, varscan2
- KCNG3 | c.1249C>T p.H417Y | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.968); catalogued as COSV100045545; called by muse, mutect2, varscan2
- KCNJ10 | c.365C>T p.S122F | Missense Mutation (SNP) | VAF 110/193 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100927968; called by muse, mutect2, varscan2
- KCNK16 | c.789G>T p.Q263H | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs746056366, COSV100949364; called by muse, varscan2
- KCNQ5 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV100573376; called by muse, mutect2, varscan2
- KCNT1 | c.842C>T p.S281F (on ENST00000488444; = p.S300F on NM_020822.3) | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV99707004; called by muse, mutect2, varscan2
- KCNT2 | c.431T>A p.I144K | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV99657441; called by muse, mutect2
- KCTD13 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs769549759, COSV100441893; called by muse, mutect2, varscan2
- KCTD8 | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV100760237; called by muse, mutect2, varscan2
- KERA | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777653993, COSV57130042; called by muse, mutect2, varscan2
- KIAA1217 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 68/184 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100287461; called by muse, mutect2, varscan2
- KIF4B | c.3422C>T p.S1141F | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101469429; called by muse, mutect2, varscan2
- KIR2DL1 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 188/1003 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.104); catalogued as rs746748835, COSV52412106; called by muse, mutect2, varscan2
- KIR2DL4 | c.1177G>A p.G393R (on ENST00000396284; = p.G319R on NM_001080770.2) | Missense Mutation (SNP) | VAF 72/202 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs777751353; called by muse, mutect2, varscan2
- KLHL13 | c.1163G>A p.G388E | Missense Mutation (SNP) | VAF 63/77 reads (82%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV99452729; called by muse, mutect2, varscan2
- KLHL6 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 84/142 reads (59%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.468); catalogued as COSV100385123; called by muse, mutect2, varscan2
- KMT2B | c.5201C>T p.S1734F | Missense Mutation (SNP) | VAF 191/522 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55862799; called by muse, mutect2, varscan2
- KNG1 | c.1130C>T p.S377L | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV99405953; called by muse, mutect2, varscan2
- LAIR1 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.9); PolyPhen benign (0.113); catalogued as rs778632174, COSV100479598, COSV100479974; called by muse, mutect2, varscan2
- LALBA | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs1457638223, COSV56395710; called by muse, mutect2, varscan2
- LAMC1 | c.4474G>T p.A1492S | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.444); catalogued as COSV99280667; called by muse, mutect2, varscan2
- LCOR | c.2474C>T p.S825F | Missense Mutation (SNP) | VAF 65/144 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99617281; called by muse, mutect2, varscan2
- LHCGR | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs868082406, COSV99684355; called by muse, mutect2, varscan2
- LILRA2 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 85/357 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs770183945, COSV52191773; called by muse, mutect2, varscan2
- LILRB4 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV99553503, COSV99554233; called by muse, mutect2, varscan2
- LPA | c.4459C>T p.P1487S | Missense Mutation (SNP) | VAF 58/83 reads (70%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as rs1277751211, COSV100308319, COSV60313909; called by muse, mutect2, varscan2
- LRP1 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99677721; called by muse, mutect2, varscan2
- LRP1B | c.822G>A p.W274* | Nonsense Mutation (SNP) | VAF 32/111 reads (29%) | catalogued as COSV101262157; called by muse, mutect2, varscan2
- LRRC20 | c.361G>A p.A121T (on ENST00000355790 / NM_207119.3; = p.A71T on NM_018239.4) | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.81); PolyPhen benign (0.137); catalogued as COSV62937984; called by muse, mutect2, varscan2
- MAGEA12 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 76/104 reads (73%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs199979249, COSV100757106, COSV63294436; called by muse, mutect2, varscan2
- MAGEC1 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 103/142 reads (73%) | catalogued as rs145052423, COSV53569341, COSV99596791; called by muse, mutect2, varscan2
- MAGEC1 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 251/334 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs866448898, COSV53567920; called by muse, mutect2, varscan2
- MAMDC2 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 80/200 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65856709; called by muse, mutect2, varscan2
- MAML3 | c.2909G>A p.G970D | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as rs866830035, COSV101558379, COSV101558563; called by muse, mutect2, varscan2
- MANEA | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 55/83 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as rs145603966; called by muse, mutect2, varscan2
- MAP1A | c.7324C>T p.R2442W | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs761287782, COSV55811718; called by muse, mutect2, varscan2
- MAP3K10 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1338691199, COSV99454954; called by muse, mutect2, varscan2
- MAP3K2 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1167257235, COSV100789410; called by muse, mutect2, varscan2
- MAP4K4 | c.2525C>T p.S842F (on ENST00000347699 / NM_001242559.2; = p.S760F on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.931); catalogued as COSV100156141; called by muse, mutect2, varscan2
- MARCHF10 | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV100248721; called by muse, mutect2, varscan2
- MAST3 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 102/250 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV53224163; called by muse, mutect2, varscan2
- MAST3 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV99446530; called by muse, mutect2, varscan2
- MBD5 | c.3652C>T p.H1218Y | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs753060251, COSV68698473; ClinVar: likely benign; called by muse, mutect2, varscan2
- METTL14 | c.331C>T p.Q111* | Nonsense Mutation (SNP) | VAF 42/142 reads (30%) | catalogued as COSV101183430; called by muse, mutect2, varscan2
- MGAT5 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs758454135, COSV56101478; called by muse, mutect2, varscan2
- MKS1 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100439862; called by muse, mutect2, varscan2
- MKX | c.728G>A p.G243E | Missense Mutation (SNP) | VAF 83/206 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65391852; called by muse, mutect2, varscan2
- MMP11 | c.134G>A p.R45K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV99303455; called by muse, mutect2, varscan2
- MORC2 | c.1173C>G p.I391M (on ENST00000397641 / NM_001303256.3; = p.I329M on NM_014941.3) | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99310597; called by muse, mutect2, varscan2
- MORC2 | c.1172T>G p.I391S (on ENST00000397641 / NM_001303256.3; = p.I329S on NM_014941.3) | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99310599; called by muse, mutect2, varscan2
- MPHOSPH10 | c.362A>G p.E121G | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.475); catalogued as COSV99731354; called by muse, mutect2
- MPHOSPH6 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); catalogued as COSV99259216, COSV99259417; called by muse, mutect2, varscan2
- MPP7 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.455); catalogued as rs765523927, COSV61730152; called by muse, mutect2, varscan2
- MRC2 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100316878; called by muse, mutect2, varscan2
- MUC16 | c.34174C>T p.P11392S | Missense Mutation (SNP) | VAF 90/207 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.179); catalogued as COSV101202154, COSV67467265; called by muse, mutect2, varscan2
- MUC16 | c.33809C>T p.P11270L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.451); catalogued as COSV67491883; called by muse, mutect2, varscan2
- MUC16 | c.23108C>T p.S7703F | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as COSV67451909; called by muse, mutect2, varscan2
- MUC16 | c.21761C>T p.S7254F | Missense Mutation (SNP) | VAF 97/234 reads (41%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.019); catalogued as COSV67462904; called by muse, mutect2, varscan2
- MUC16 | c.15968G>A p.W5323* | Nonsense Mutation (SNP) | VAF 39/93 reads (42%) | catalogued as COSV101202155; called by muse, mutect2, varscan2
- MXRA5 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 118/155 reads (76%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99479767; called by muse, mutect2, varscan2
- MYBPHL | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV99861262; called by muse, mutect2
- MYCBP2 | c.8452G>A p.A2818T (on ENST00000357337; = p.A2856T on NM_015057.5) | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV100632387; called by muse, mutect2, varscan2
- MYH8 | c.4568G>A p.G1523E | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as rs763779942, COSV101238978; called by muse, mutect2, varscan2
- MYO1B | c.3244C>T p.L1082F (on ENST00000304164; = p.L1024F on NM_012223.5) | Missense Mutation (SNP) | VAF 77/207 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.912); catalogued as COSV100270301, COSV58438153; called by muse, mutect2, varscan2
- NCKAP1L | c.1505C>A p.P502H | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV99515844; called by muse, mutect2, varscan2
- NCR3 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.937); catalogued as COSV99279237; called by muse, mutect2, varscan2
- NEB | c.16666G>A p.A5556T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99428931; called by muse, mutect2, varscan2
- NECTIN1 | c.458C>T p.T153I | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as COSV50610524; called by muse, mutect2, varscan2
- NEDD1 | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV99901447; called by muse, mutect2, varscan2
- NEGR1 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100166767; called by muse, mutect2, varscan2
- NEK5 | c.1971G>A p.W657* | Nonsense Mutation (SNP) | VAF 26/76 reads (34%) | catalogued as COSV100839324; called by muse, mutect2, varscan2
- NEO1 | c.3796C>T p.H1266Y | Missense Mutation (SNP) | VAF 76/238 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as COSV99982964; called by muse, mutect2, varscan2
- NEO1 | c.4102C>T p.P1368S | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV56071014; called by muse, mutect2, varscan2
- NFE2 | c.1006C>T p.H336Y | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.265); catalogued as COSV100380865; called by muse, mutect2, varscan2
- NOD2 | c.3019C>T p.L1007F | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs761083670, COSV56056200; called by muse, mutect2, varscan2
- NOS1 | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 85/221 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100501579; called by muse, mutect2, varscan2
- NPTXR | c.1006A>C p.T336P | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100285604; called by muse, mutect2, varscan2
- NSA2 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs536760760, COSV57188964; called by muse, mutect2, varscan2
- NSD2 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100374058; called by muse, mutect2, varscan2
- NTNG1 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 107/297 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1452420748, COSV99640087; called by muse, mutect2, varscan2
- NXPE1 | c.1472G>A p.G491E (on ENST00000424269; = p.G349E on NM_152315.5) | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); catalogued as COSV99321197; called by muse, mutect2, varscan2
- OR10A3 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100660350; called by muse, mutect2, varscan2
- OR10A5 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.654); catalogued as COSV55054018; called by muse, mutect2, varscan2
- OR10G8 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 83/224 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs745803466, COSV70908204; called by muse, mutect2, varscan2
- OR2B6 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV99773748; called by muse, mutect2, varscan2
- OR2T35 | c.488C>T p.T163I | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs570262026; called by mutect2, varscan2
- OR2W1 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as COSV101013953, COSV65851748; called by muse, mutect2, varscan2
- OR4X1 | c.773G>A p.R258K | Missense Mutation (SNP) | VAF 76/209 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100186870, COSV60722446; called by muse, mutect2, varscan2
- OR51A7 | c.910G>A p.G304R | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as COSV63788408, COSV63789003; called by muse, mutect2, varscan2
- OR51B2 | c.56A>G p.E19G | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100173570; called by muse, mutect2, varscan2
- OR52E6 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs868025221, COSV61432022, COSV61433561; called by muse, mutect2, varscan2
- OR5H14 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 66/280 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV101454343, COSV71193561; called by muse, varscan2
- OR5H2 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 124/303 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1453993880, COSV100788884, COSV62350071; called by muse, mutect2, varscan2
- OR5H6 | c.202G>A p.D68N (on ENST00000642105; = p.D52N on NM_001005479.2) | Missense Mutation (SNP) | VAF 152/388 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV67352202; called by muse, mutect2, varscan2
- OR5W2 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV60616499; called by muse, mutect2, varscan2
- OR6F1 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 117/198 reads (59%) | SIFT tolerated (0.34); PolyPhen benign (0.037); catalogued as rs866322456, COSV57469416; called by muse, mutect2, varscan2
- OR8B2 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV100899528; called by muse, mutect2, varscan2
- OR8I2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 93/247 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs773934404, COSV56166825, COSV56168276; called by muse, mutect2, varscan2
- PALD1 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 76/211 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV54976697; called by muse, mutect2, varscan2
- PAPPA2 | c.611G>A p.R204K | Missense Mutation (SNP) | VAF 155/274 reads (57%) | SIFT tolerated (0.82); PolyPhen benign (0.005); catalogued as COSV100867262; called by muse, mutect2, varscan2
- PAPPA2 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 114/202 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as COSV62780713; called by muse, mutect2, varscan2
- PARP9 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV64451870; called by muse, mutect2, varscan2
- PCDH15 | c.2201C>T p.A734V | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.241); catalogued as COSV100229121, COSV57290429; called by muse, mutect2, varscan2
- PCDHAC1 | c.782A>G p.D261G | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99170227; called by muse, mutect2
- PCDHB14 | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs782077099, COSV53387387; called by muse, mutect2, varscan2
- PCDHB7 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.052); catalogued as rs113945814, COSV50755363; called by muse, mutect2, varscan2
- PCDHGA9 | c.1556C>T p.S519F | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99549098; called by muse, mutect2, varscan2
- PCDHGB1 | c.2240C>T p.S747F | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV53935758, COSV54019011; called by muse, mutect2, varscan2
- PCLO | c.11320G>A p.E3774K | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV61617419; called by muse, mutect2, varscan2
- PCLO | c.4443A>C p.K1481N | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV100439236; called by muse, mutect2, varscan2
- PCMTD2 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV99829615; called by muse, mutect2, varscan2
- PCOLCE | c.661T>C p.F221L | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99575801; called by muse, mutect2, varscan2
- PCYOX1 | c.648G>A p.M216I | Missense Mutation (SNP) | VAF 76/224 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs368822515; called by muse, mutect2, varscan2
- PDPN | c.461G>A p.R154Q (on ENST00000621990; = p.R230Q on NM_006474.4) | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs147446446; called by muse, mutect2, varscan2
- PDZK1IP1 | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.429); catalogued as COSV99595586; called by muse, mutect2, varscan2
- PEG3 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 107/269 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs765630906, COSV55634529; called by muse, mutect2, varscan2
- PGLS | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 114/352 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV99395815; called by muse, mutect2, varscan2
- PHF20L1 | c.840G>C p.K280N | Missense Mutation (SNP) | VAF 71/234 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55194700, COSV99622358; called by muse, mutect2, varscan2
- PIGZ | c.155C>G p.P52R | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53013194, COSV99434005; called by muse, mutect2, varscan2
- PIH1D1 | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99221262; called by muse, mutect2, varscan2
- PIKFYVE | c.1937A>C p.Q646P | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100011632; called by muse, mutect2, varscan2
- PITPNM1 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV100039533; called by muse, mutect2, varscan2
- PIWIL3 | c.2066C>G p.T689R | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs751786240, COSV100178067; called by muse, mutect2, varscan2
- PJVK | c.553C>T p.H185Y | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs1336161241, COSV100910566; called by muse, mutect2, varscan2
- PLCD4 | c.889A>G p.N297D | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.257); catalogued as COSV101346983; called by muse, mutect2, varscan2
- PLD5 | c.1159G>A p.E387K (on ENST00000442594; = p.E325K on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/280 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV59170832; called by muse, mutect2, varscan2
- PLEKHS1 | c.784G>A p.E262K (on ENST00000369310 / NM_182601.1; = p.E268K on NM_024889.5) | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.018); catalogued as COSV63055093; called by muse, mutect2, varscan2
- PLXNA2 | c.163G>A p.V55I | Missense Mutation (SNP) | VAF 74/289 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.816); catalogued as rs975879779, COSV65444068; called by muse, mutect2, varscan2
- PLXNC1 | c.4226G>A p.W1409* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | catalogued as COSV99314088; called by muse, mutect2, varscan2
- PNN | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.204); catalogued as COSV99397454; called by muse, mutect2, varscan2
- POP1 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs747368799, COSV100856179; called by muse, mutect2
- POP1 | c.565A>G p.T189A | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs1224910871, COSV100856183; called by muse, mutect2
- PPP1CA | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.031); catalogued as COSV100335099; called by muse, mutect2, varscan2
- PPP1R26 | c.1444A>T p.M482L | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.069); catalogued as COSV100778176; called by muse, mutect2, varscan2
- PPP6R2 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99324975; called by muse, mutect2, varscan2
- PRDM9 | c.1000C>T p.Q334* | Nonsense Mutation (SNP) | VAF 30/111 reads (27%) | catalogued as COSV99691495; called by muse, mutect2, varscan2
- PREX1 | c.4870G>A p.G1624S | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100906903; called by muse, mutect2, varscan2
- PREX2 | c.4210C>T p.H1404Y | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs866534903, COSV55770593; called by muse, mutect2, varscan2
- PRKAA2 | c.1214G>A p.G405E | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100982757; called by muse, mutect2, varscan2
- PRND | c.105G>A p.W35* | Nonsense Mutation (SNP) | VAF 35/106 reads (33%) | catalogued as rs868799683, COSV99999754; called by muse, mutect2, varscan2
- PRR27 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 74/218 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746412473, COSV100748932; called by muse, mutect2, varscan2
- PRSS16 | c.264G>A p.W88* | Nonsense Mutation (SNP) | VAF 60/125 reads (48%) | catalogued as rs767863958, COSV100042058; called by muse, mutect2, varscan2
- PTPN22 | c.2068C>T p.R690C (on ENST00000359785 / NM_001193431.2; = p.R635C on NM_012411.5) | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as rs200154470, COSV63085044; called by muse, mutect2, varscan2
- RAB3D | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 156/433 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV99708967; called by muse, mutect2, varscan2
- RADIL | c.1762T>G p.C588G | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.065); catalogued as COSV101271647; called by muse, mutect2, varscan2
- RAI1 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 93/251 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV99885301; called by muse, mutect2, varscan2
- RBM27 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.795); catalogued as COSV99506743; called by muse, mutect2, varscan2
- RHNO1 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100817094; called by muse, mutect2, varscan2
- RNF40 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100222403, COSV61216714; called by muse, mutect2, varscan2
- ROBO2 | c.2328+2T>A p.X776_splice | Splice Site (SNP) | VAF 27/72 reads (38%) | catalogued as COSV100170583; called by muse, mutect2, varscan2
- RP1 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55119426; called by muse, mutect2, varscan2
- RP1 | c.2080G>A p.G694R | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as COSV99609171; called by muse, mutect2, varscan2
- RP1 | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV55117041; called by muse, mutect2, varscan2
- RP1 | c.5548C>T p.H1850Y | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.355); catalogued as rs924460004, COSV99609173; called by muse, mutect2, varscan2
- RPTN | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 138/488 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as rs370006914, COSV60166809; called by muse, mutect2, varscan2
- RYR1 | c.12322C>T p.Q4108* | Nonsense Mutation (SNP) | VAF 41/108 reads (38%) | catalogued as COSV62112232; called by muse, mutect2, varscan2
- SAFB | c.2446C>T p.P816S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1030672561, COSV99412707, COSV99412757; called by muse, mutect2, varscan2
- SALL1 | c.3106C>T p.R1036C | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs765451610, COSV51757286; called by muse, mutect2, varscan2
- SALL3 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV73306015; called by muse, varscan2
- SAMD7 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 99/237 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100157129; called by muse, mutect2, varscan2
- SATB1 | c.1762C>T p.P588S | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as COSV100113532; called by muse, mutect2, varscan2
- SCN10A | c.5320C>T p.P1774S | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101479580; called by muse, mutect2, varscan2
- SCN8A | c.5156C>T p.P1719L | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD061468, COSV100634373; called by muse, mutect2, varscan2
- SCYL2 | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.661); catalogued as COSV100675331; called by muse, mutect2, varscan2
- SEC31B | c.2896C>T p.L966F | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.05); catalogued as COSV100947508; called by muse, mutect2, varscan2
- SERPINB7 | c.861G>A p.M287I | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV60535399; called by muse, mutect2, varscan2
- SETD3 | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0.014); catalogued as rs943185195, COSV100075592; called by muse, mutect2, varscan2
- SH3PXD2A | c.2461G>A p.D821N (on ENST00000369774 / NM_001365079.1; = p.D793N on NM_014631.2) | Missense Mutation (SNP) | VAF 73/195 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs1288697872, COSV60116648; called by muse, mutect2, varscan2
- SHC3 | c.1742G>A p.G581E | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.14); catalogued as COSV101012449; called by muse, mutect2, varscan2
- SIKE1 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 78/134 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50258629; called by muse, mutect2, varscan2
- SKAP2 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV61722650; called by muse, mutect2, varscan2
- SLC12A5 | c.1363C>T p.P455S (on ENST00000454036 / NM_001134771.2; = p.P432S on NM_020708.5) | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99717066; called by muse, mutect2, varscan2
- SLC16A14 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); catalogued as COSV99725968; called by muse, mutect2, varscan2
- SLC24A1 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs760771112, COSV99978365; called by muse, mutect2, varscan2
- SLC26A5 | c.1868G>A p.S623N | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100100364; called by muse, mutect2, varscan2
- SLC35F3 | c.847C>T p.P283S (on ENST00000366617 / NM_001300845.1; = p.P352S on NM_173508.4) | Missense Mutation (SNP) | VAF 94/357 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as rs867588567, COSV64018284; called by muse, mutect2, varscan2
- SLC39A13 | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 68/192 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs769680848, COSV100712712; called by muse, mutect2, varscan2
- SLC39A13 | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 69/192 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100712713; called by muse, mutect2, varscan2
- SLC39A13 | c.283A>C p.T95P | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV100712715; called by muse, mutect2, varscan2
- SLC39A9 | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99220743; called by muse, mutect2, varscan2
- SLC4A5 | c.2128C>T p.L710F | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV100698118; called by muse, mutect2, varscan2
- SLC5A8 | c.1121G>A p.R374K | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV101610622, COSV73310460; called by muse, mutect2, varscan2
- SLC9A4 | c.2053G>A p.D685N | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99763672; called by muse, mutect2, varscan2
- SLCO1B3 | c.919C>T p.Q307* | Nonsense Mutation (SNP) | VAF 35/87 reads (40%) | catalogued as COSV53931962, COSV99682418; called by muse, mutect2, varscan2
- SLCO1B3 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.238); catalogued as rs141602442; called by muse, mutect2, varscan2
- SLCO1B3 | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758007322, COSV99682419; called by muse, mutect2, varscan2
- SLCO6A1 | c.2012G>A p.G671E | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV101135169, COSV65812520; called by muse, mutect2
- SLCO6A1 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV65811703; called by muse, mutect2, varscan2
- SLF1 | c.3073C>T p.L1025F | Missense Mutation (SNP) | VAF 102/259 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV99476437; called by muse, varscan2
- SLIT2 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 84/223 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV99888072; called by muse, mutect2, varscan2
- SLITRK6 | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV101233314; called by muse, mutect2, varscan2
- SMC2 | c.2002C>T p.R668* | Nonsense Mutation (SNP) | VAF 85/239 reads (36%) | catalogued as COSV99659890; called by muse, mutect2, varscan2
- SMCHD1 | c.5659C>T p.R1887W | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1462790313, COSV99861486; called by muse, mutect2, varscan2
- SMCO3 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 67/164 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs755400649, COSV99660955; called by muse, mutect2, varscan2
- SMR3B | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs986495178, COSV100513475; called by muse, mutect2, varscan2
- SNAPC2 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as rs1376253274, COSV99564403; called by muse, mutect2, varscan2
- SNX18 | c.1084C>T p.H362Y | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.781); catalogued as COSV100410603; called by muse, mutect2, varscan2
- SORCS1 | c.1084T>G p.F362V | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99551164; called by muse, mutect2, varscan2
- SORCS3 | c.2128G>A p.G710R | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100863920; called by muse, mutect2, varscan2
- SORCS3 | c.2129G>A p.G710E | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63798793; called by muse, mutect2, varscan2
- SPAG17 | c.5537C>T p.T1846I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100310939; called by muse, mutect2, varscan2
- SPAM1 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99773625; called by muse, mutect2, varscan2
- SPG11 | c.1882C>T p.H628Y | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1395150167, COSV99969406; called by muse, mutect2, varscan2
- SPHKAP | c.4102C>T p.L1368F | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100764639; called by muse, mutect2, varscan2
- SPOCD1 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99930449; called by muse, mutect2, varscan2
- SPON1 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as COSV100116792; called by muse, mutect2, varscan2
- SRGAP2 | c.1787G>A p.R596K (on ENST00000624873 / NM_001170637.4; = p.R597K on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.53); catalogued as COSV99833385; called by muse, mutect2, varscan2
- STKLD1 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV64315892; called by muse, mutect2, varscan2
- STMN2 | c.417G>A p.M139I | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV55218029; called by muse, mutect2, varscan2
- STRA6 | c.1814G>A p.S605N | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.167); catalogued as COSV99997616; called by muse, mutect2, varscan2
- STRC | c.4565G>A p.G1522E | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV100294683; called by muse, mutect2, varscan2
- STRC | c.4564G>A p.G1522R | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs763904943, COSV100294727; called by muse, mutect2, varscan2
- STRIP1 | c.2492C>T p.S831F | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV63930349; called by muse, mutect2, varscan2
- STXBP5L | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs267599561, COSV56501238; called by muse, mutect2, varscan2
- SVEP1 | c.7669G>A p.D2557N | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1203576825, COSV99930055; called by muse, mutect2, varscan2
- SVIL | c.1994G>A p.R665Q | Missense Mutation (SNP) | VAF 87/223 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1189640266, COSV100881623; called by muse, mutect2, varscan2
- SYNE2 | c.5318C>T p.P1773L | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100648617, COSV59971986; called by muse, mutect2, varscan2
- SYNE2 | c.19261C>T p.H6421Y | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100648618; called by muse, mutect2, varscan2
- SYNPO2 | c.2066G>A p.R689K | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.432); catalogued as COSV100206558; called by muse, mutect2, varscan2
- SYT10 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV57343290; called by muse, varscan2
- SYT16 | c.1487C>T p.S496L | Missense Mutation (SNP) | VAF 75/191 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as COSV70859382; called by muse, mutect2, varscan2
- SYT3 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.977); catalogued as COSV100144374; called by muse, mutect2, varscan2
- TAF4 | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as COSV99435253; called by muse, mutect2, varscan2
- TDGF1 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 78/200 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV56124842; called by muse, mutect2
- TECTA | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV99881893; called by muse, mutect2, varscan2
- TERF2IP | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs527772778, COSV55613727; called by muse, varscan2
- THSD7B | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 28/65 reads (43%) | catalogued as COSV99759368; called by muse, mutect2, varscan2
- TIAM2 | c.722G>A p.S241N | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as COSV100020468; called by muse, mutect2, varscan2
- TIGD3 | c.1102G>A p.G368S | Missense Mutation (SNP) | VAF 61/187 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs893859728, COSV52888842, COSV99361839; called by muse, mutect2, varscan2
- TMEM182 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs535703369, COSV68424998; called by muse, mutect2
- TMEM209 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100390686; called by muse, mutect2, varscan2
- TMIGD2 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 202/476 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1288484768, COSV56667322; called by muse, mutect2, varscan2
- TNN | c.2083C>T p.Q695* | Nonsense Mutation (SNP) | VAF 36/157 reads (23%) | catalogued as COSV99513314; called by muse, mutect2, varscan2
- TOP2A | c.2668C>T p.P890S | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101396424; called by muse, mutect2, varscan2
- TPSD1 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs368387817, COSV99274287; called by muse, mutect2, varscan2
- TRANK1 | c.8335C>T p.H2779Y | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as rs867517645, COSV100085200; called by muse, mutect2, varscan2
- TRBV28 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs745393218; called by muse, mutect2, varscan2
- TRHDE | c.2201C>T p.P734L | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as COSV99673066; called by muse, mutect2, varscan2
- TRHDE | c.2287C>T p.P763S | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as COSV53831788; called by muse, mutect2, varscan2
- TRIM29 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as COSV100532088; called by muse, mutect2, varscan2
- TRIM29 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.133); catalogued as COSV100532091; called by muse, mutect2, varscan2
- TRPC5 | c.1981T>A p.F661I | Missense Mutation (SNP) | VAF 101/131 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99463216; called by muse, mutect2, varscan2
- TRPC6 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 77/203 reads (38%) | catalogued as COSV60255073; called by muse, mutect2, varscan2
- TRPM1 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV56635979, COSV99856901; called by muse, mutect2, varscan2
- TRPM2 | c.3050G>A p.R1017K | Missense Mutation (SNP) | VAF 219/576 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV100309477; called by muse, mutect2, varscan2
- TSKS | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99883800; called by muse, mutect2, varscan2
- TSPAN2 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 172/335 reads (51%) | SIFT tolerated (0.87); PolyPhen benign (0.041); catalogued as COSV65690485; called by muse, mutect2, varscan2
- TTN | c.49619G>A p.G16540E (on ENST00000591111; = p.G9116E on NM_003319.4) | Missense Mutation (SNP) | VAF 66/174 reads (38%) | PolyPhen benign (0.116); catalogued as COSV100634835; called by muse, mutect2, varscan2
- TTN | c.37079G>A p.G12360E (on ENST00000591111; = p.G4936E on NM_003319.4) | Missense Mutation (SNP) | VAF 41/128 reads (32%) | PolyPhen probably damaging (0.964); catalogued as COSV100634838; called by muse, mutect2, varscan2
- TTN | c.34288G>A p.E11430K (on ENST00000591111; = p.E12493K on NM_001267550.2) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | PolyPhen benign (0); catalogued as rs1426948805, COSV100616895, COSV100634842; ClinVar: uncertain significance; called by mutect2, varscan2
- TTN | c.16559G>A p.G5520E (on ENST00000591111; = p.G4593E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/224 reads (37%) | PolyPhen possibly damaging (0.811); catalogued as COSV60260706; called by muse, mutect2, varscan2
- TTN | c.4678G>A p.E1560K (on ENST00000591111; = p.E1514K on NM_003319.4) | Missense Mutation (SNP) | VAF 35/90 reads (39%) | PolyPhen probably damaging (0.994); catalogued as COSV100594895; called by muse, mutect2, varscan2
- TTN | c.2503G>A p.A835T (on ENST00000591111; = p.A789T on NM_003319.4) | Missense Mutation (SNP) | VAF 38/102 reads (37%) | PolyPhen possibly damaging (0.859); catalogued as COSV100634845; called by muse, mutect2, varscan2
- TUBGCP6 | c.2800C>T p.P934S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV99956504; called by muse, mutect2, varscan2
- TUT4 | c.2522C>T p.S841L | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.141); catalogued as rs765761860, COSV99931920, COSV99932961; called by muse, mutect2, varscan2
- TUT4 | c.1658G>A p.R553K | Missense Mutation (SNP) | VAF 79/189 reads (42%) | SIFT tolerated (0.75); PolyPhen benign (0.011); catalogued as COSV99932149, COSV99932963; called by muse, mutect2, varscan2
- UBN1 | c.2971C>T p.P991S | Missense Mutation (SNP) | VAF 70/197 reads (36%) | SIFT tolerated, low confidence (0.51); PolyPhen possibly damaging (0.641); catalogued as COSV99278790; called by muse, mutect2, varscan2
- UBQLN3 | c.1670G>A p.G557E | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs761469787, COSV100294030; called by muse, mutect2, varscan2
- UBR3 | c.4867G>A p.E1623K | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV99775196; called by muse, mutect2, varscan2
- UBTF | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as COSV100256202, COSV57185659; called by muse, mutect2, varscan2
- UGT2B28 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 138/355 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV100159106; called by muse, mutect2, varscan2
- UNC13C | c.1579C>T p.H527Y | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99524108; called by muse, mutect2, varscan2
- UNC13D | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV99257783; called by muse, mutect2, varscan2
- UNC45B | c.1651G>A p.D551N | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99269379; called by muse, mutect2, varscan2
- USHBP1 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs899745421, COSV53105318; called by muse, mutect2, varscan2
- USP13 | c.1999C>T p.P667S | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV99831883; called by muse, mutect2, varscan2
- USP32 | c.448C>T p.L150F | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100343059; called by muse, mutect2, varscan2
- USP34 | c.9394G>A p.D3132N | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as COSV101277297; called by muse, mutect2, varscan2
- UTP20 | c.2516C>T p.S839F | Missense Mutation (SNP) | VAF 65/203 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99882743; called by muse, mutect2, varscan2
- UTS2 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 143/244 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.355); catalogued as COSV50013182; called by muse, mutect2, varscan2
- VAMP7 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 78/207 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as rs1439223778, COSV99387752; called by muse, mutect2, varscan2
- VARS1 | c.3320C>T p.A1107V | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT tolerated (0.27); PolyPhen benign (0.11); catalogued as COSV100791859, COSV63304977; called by muse, mutect2, varscan2
- VCX | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 91/285 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs767257579, COSV100406426; called by muse, varscan2
- VCX3A | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 70/333 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV101129994; called by muse, varscan2
- VWF | c.1291C>T p.Q431* | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | catalogued as COSV99780547; called by muse, mutect2, varscan2
- WDR5 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV62273944; called by muse, mutect2, varscan2
- ZC3H12B | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT tolerated (0.34); PolyPhen benign (0.368); catalogued as rs776451042, COSV100162205; called by muse, mutect2, varscan2
- ZCCHC14 | c.503T>G p.V168G (on ENST00000268616; = p.V305G on NM_015144.3) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.138); catalogued as COSV99234720; called by muse, mutect2, varscan2
- ZDHHC8 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100273316, COSV57709539; called by muse, mutect2, varscan2
- ZEB1 | c.1297C>T p.Q433* | Nonsense Mutation (SNP) | VAF 33/98 reads (34%) | catalogued as COSV100315283; called by muse, mutect2, varscan2
- ZFHX4 | c.1774G>T p.G592C | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.575); catalogued as COSV99268919; called by muse, mutect2, varscan2
- ZFHX4 | c.7225C>T p.P2409S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.124); catalogued as rs1158917761, COSV99268922; called by muse, mutect2, varscan2
- ZIM3 | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 70/203 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267605723, COSV54142975; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1693T>C p.C565R | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.618); catalogued as rs767713061, COSV99837804; called by muse, mutect2, varscan2
- ZMAT4 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 130/315 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV99911616; called by muse, mutect2, varscan2
- ZNF184 | c.1234C>T p.H412Y | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99280191; called by muse, mutect2, varscan2
- ZNF197 | c.1364A>G p.K455R | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as COSV100482319; called by muse, mutect2, varscan2
- ZNF227 | c.640C>T p.H214Y | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs1408686486, COSV100480655; called by muse, mutect2, varscan2
- ZNF253 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV63037865; called by muse, mutect2, varscan2
- ZNF385A | c.635C>T p.S212F (on ENST00000338010 / NM_001130967.3; = p.S192F on NM_015481.3) | Missense Mutation (SNP) | VAF 88/244 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100567036; called by muse, mutect2, varscan2
- ZNF385D | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 20/46 reads (43%) | catalogued as COSV55763422; called by muse, mutect2, varscan2
- ZNF408 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as rs756397869, COSV100305732; called by muse, mutect2, varscan2
- ZNF423 | c.113G>A p.G38E (on ENST00000563137 / NM_001379286.1; = p.G30E on NM_015069.4) | Missense Mutation (SNP) | VAF 89/234 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.062); catalogued as COSV52196392; called by muse, mutect2, varscan2
- ZNF431 | c.1682C>T p.S561L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs1263115312, COSV100219155; called by muse, mutect2, varscan2
- ZNF438 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV100062943; called by muse, mutect2, varscan2
- ZNF563 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 111/269 reads (41%) | catalogued as COSV99536851; called by muse, mutect2, varscan2
- ZNF570 | c.899A>G p.K300R | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV100356325; called by muse, mutect2, varscan2
- ZNF667 | c.1708C>T p.L570F | Missense Mutation (SNP) | VAF 75/190 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.816); catalogued as COSV99411106; called by muse, mutect2, varscan2
- ZNF804A | c.3577C>T p.P1193S | Missense Mutation (SNP) | VAF 124/351 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.813); catalogued as COSV56477286; called by muse, mutect2, varscan2
- ZNF813 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as COSV101125032; called by muse, mutect2
- ZSCAN10 | c.817G>A p.E273K (on ENST00000252463; = p.E328K on NM_032805.3) | Missense Mutation (SNP) | VAF 111/293 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99374144; called by muse, mutect2, varscan2
- ANKRD30A | c.2425C>T p.L809F (on ENST00000611781; = p.L753F on NM_052997.2) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.19); called by mutect2, varscan2
- AOC2 | c.1720dup p.S574Ffs*14 | Frame Shift Ins (INS) | VAF 43/137 reads (31%) | called by mutect2, pindel, varscan2
- COPS3 | c.105del p.A36Rfs*29 | Frame Shift Del (DEL) | VAF 32/104 reads (31%) | called by mutect2, pindel*, varscan2
- EDAR | c.937del p.S313Lfs*59 | Frame Shift Del (DEL) | VAF 40/156 reads (26%) | called by mutect2, pindel, varscan2
- KIR3DL3 | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 93/255 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- LAMP2 | c.58del p.V20Sfs*14 | Frame Shift Del (DEL) | VAF 62/95 reads (65%) | called by mutect2, pindel, varscan2
- NCOR1 | c.1441_1460del p.T481* | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- SCNM1 | c.212-6_226del p.X71_splice | Splice Site (DEL) | VAF 67/154 reads (44%) | called by mutect2, pindel, varscan2
- TAF1A | c.761del p.D254Vfs*30 | Frame Shift Del (DEL) | VAF 52/116 reads (45%) | called by mutect2, pindel*, varscan2
- AAK1 | c.1149C>T p.P383= | Silent (SNP) | VAF 76/191 reads (40%) | catalogued as COSV101117272; called by muse, mutect2, varscan2
- ABCC9 | c.3729G>A p.S1243= | Silent (SNP) | VAF 77/248 reads (31%) | catalogued as rs140182559; ClinVar: likely benign; called by muse, mutect2, varscan2
- AC100868.1 | c.987C>T p.L329= | Silent (SNP) | VAF 75/295 reads (25%) | catalogued as COSV51848640; called by muse, mutect2, varscan2
- ACSM2B | c.492C>T p.I164= | Silent (SNP) | VAF 108/259 reads (42%) | catalogued as rs759928318, COSV100313260; called by muse, mutect2, varscan2
- ADAMTS6 | c.738G>A p.V246= | Silent (SNP) | VAF 54/152 reads (36%) | catalogued as COSV101125560; called by muse, mutect2, varscan2
- ADAMTS8 | c.2394C>T p.F798= | Silent (SNP) | VAF 124/366 reads (34%) | catalogued as rs1323155034, COSV57297291; called by muse, mutect2, varscan2
- ADGRE1 | c.1179C>T p.F393= | Silent (SNP) | VAF 55/137 reads (40%) | catalogued as COSV99165565; called by muse, mutect2, varscan2
- ADGRL2 | c.201G>A p.T67= | Silent (SNP) | VAF 60/155 reads (39%) | catalogued as rs985530151, COSV99592003; called by muse, mutect2, varscan2
- ADGRV1 | c.3876C>T p.F1292= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV101316671, COSV67990432; called by muse, mutect2, varscan2
- ADGRV1 | c.15183G>A p.G5061= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV101316672; called by mutect2, varscan2
- AGMO | c.270G>A p.R90= | Silent (SNP) | VAF 47/149 reads (32%) | catalogued as COSV100694909, COSV61125179; called by muse, mutect2, varscan2
- AGTR1 | c.918G>A p.G306= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as rs1064535, COSV62557903; called by muse, mutect2, varscan2
- ANKFN1 | c.600A>G p.E200= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100594344; called by muse, mutect2, varscan2
- AP5B1 | c.799C>T p.L267= | Silent (SNP) | VAF 49/120 reads (41%) | catalogued as COSV100376192; called by muse, mutect2, varscan2
- APBA2 | c.270C>T p.L90= | Silent (SNP) | VAF 101/250 reads (40%) | catalogued as COSV68789079; called by muse, mutect2, varscan2
- AQP11 | c.21C>T p.L7= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100547414; called by muse, mutect2, varscan2
- ARNTL2 | c.1362C>T p.F454= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as COSV99668168; called by muse, mutect2, varscan2
- ARPP21 | c.597C>T p.V199= | Silent (SNP) | VAF 55/131 reads (42%) | catalogued as COSV99493733; called by muse, mutect2, varscan2
- ATXN7 | c.1995C>T p.S665= | Silent (SNP) | VAF 46/139 reads (33%) | catalogued as COSV99895557; called by muse, mutect2, varscan2
- AZGP1 | c.792C>T p.S264= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV52798171; called by muse, mutect2, varscan2
- BCLAF1 | c.519C>T p.P173= | Silent (SNP) | VAF 72/289 reads (25%) | catalogued as rs749557027, COSV100786740, COSV100787130; called by muse, mutect2, varscan2
- BIRC6 | c.14055C>A p.T4685= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV70204333; called by muse, mutect2, varscan2
- BRAT1 | c.765C>A p.A255= | Silent (SNP) | VAF 35/121 reads (29%) | catalogued as COSV100500747; called by muse, mutect2, varscan2
- BRINP1 | c.2139G>A p.G713= | Silent (SNP) | VAF 61/165 reads (37%) | catalogued as COSV56296505, COSV56307061; called by muse, mutect2, varscan2
- BRINP1 | c.456G>A p.R152= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV99777204; called by muse, mutect2, varscan2
- C14orf39 | c.522C>T p.P174= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100408188; called by muse, mutect2, varscan2
- C5AR2 | c.963G>A p.V321= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as COSV99953916; called by muse, mutect2, varscan2
- CACNG3 | c.882C>T p.S294= | Silent (SNP) | VAF 61/158 reads (39%) | catalogued as COSV99136899; called by muse, mutect2, varscan2
- CADM3 | c.600G>A p.R200= (on ENST00000368125 / NM_001127173.3; = p.R234= on NM_021189.5) | Silent (SNP) | VAF 31/97 reads (32%) | catalogued as COSV100930442; called by muse, mutect2, varscan2
- CALCR | c.1089C>T p.I363= (on ENST00000649521 / NM_001164737.2; = p.I347= on NM_001742.4) | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV64013135; called by muse, mutect2, varscan2
- CAMK1G | c.400C>T p.L134= | Silent (SNP) | VAF 39/185 reads (21%) | catalogued as COSV99151663, COSV99152340; called by muse, mutect2, varscan2
- CASP1 | c.1203C>T p.F401= (on ENST00000436863 / NM_033292.4; = p.F380= on NM_001223.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as rs775408300, COSV99508211; called by muse, mutect2, varscan2
- CASR | c.549C>T p.F183= | Silent (SNP) | VAF 94/245 reads (38%) | catalogued as rs779857648, COSV99949586; called by muse, mutect2, varscan2
- CCDC115 | c.183C>T p.S61= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs372936718; called by muse, mutect2, varscan2
- CCNP | c.231A>G p.E77= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs1160560027, COSV99695952; called by muse, mutect2, varscan2
- CD300LG | c.369C>T p.F123= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as rs776427136, COSV53225012; called by muse, mutect2, varscan2
- CDA | c.213C>T p.I71= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV66752019; called by muse, mutect2, varscan2
- CDH18 | c.1110G>A p.L370= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as COSV99938983; called by muse, mutect2, varscan2
- CDHR1 | c.1008C>T p.T336= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as rs547534493, COSV60560681; called by muse, mutect2, varscan2
- CELA2A | c.786C>T p.I262= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as COSV100657587; called by muse, mutect2, varscan2
- CENPP | c.345A>G p.T115= | Silent (SNP) | VAF 70/178 reads (39%) | catalogued as rs1329641382, COSV100981445; called by muse, mutect2, varscan2
- CEP120 | c.819C>T p.L273= | Silent (SNP) | VAF 58/161 reads (36%) | catalogued as COSV100071557; called by muse, mutect2, varscan2
- CFAP58 | c.375G>A p.E125= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV100459161; called by muse, mutect2, varscan2
- CHAT | c.963C>T p.F321= | Silent (SNP) | VAF 98/239 reads (41%) | catalogued as COSV100341089; called by muse, mutect2, varscan2
- CHGB | c.303G>A p.R101= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV100973153; called by muse, mutect2
- CHRNA2 | c.1561C>T p.L521= | Silent (SNP) | VAF 51/143 reads (36%) | catalogued as rs1427296744, COSV99532587; called by muse, mutect2, varscan2
- CNTN1 | c.1698G>A p.G566= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as COSV100752007; called by muse, mutect2, varscan2
- CNTNAP3 | c.2418C>T p.F806= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs772923010, COSV99904095; called by muse, mutect2, varscan2
- COLQ | c.1242G>A p.V414= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV101082613; called by muse, mutect2, varscan2
- CPXM1 | c.2031C>T p.G677= | Silent (SNP) | VAF 43/95 reads (45%) | catalogued as COSV101013862; called by muse, mutect2, varscan2
- CPXM2 | c.1053G>A p.L351= | Silent (SNP) | VAF 176/479 reads (37%) | catalogued as COSV99583570; called by muse, mutect2, varscan2
- CSMD1 | c.8820G>A p.K2940= (on ENST00000520002; = p.K2939= on NM_033225.6) | Silent (SNP) | VAF 82/210 reads (39%) | catalogued as rs1449384433, COSV100154870; called by muse, mutect2, varscan2
- CSMD2 | c.2913G>A p.L971= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV53880848; called by muse, mutect2, varscan2
- CSNK2A1 | c.582C>T p.S194= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV99424792; called by muse, mutect2, varscan2
- CTAGE6 | c.1440G>A p.R480= | Silent (SNP) | VAF 18/151 reads (12%) | catalogued as COSV101417819; called by muse, mutect2, varscan2
- CX3CR1 | c.357C>T p.F119= | Silent (SNP) | VAF 61/165 reads (37%) | catalogued as COSV100843311; called by muse, mutect2, varscan2
- CXCL12 | c.105C>T p.F35= | Silent (SNP) | VAF 92/242 reads (38%) | catalogued as rs1316806287, COSV100639090, COSV59108018; called by muse, mutect2, varscan2
- CYP24A1 | c.309C>T p.S103= | Silent (SNP) | VAF 50/124 reads (40%) | catalogued as COSV99398684; called by muse, mutect2, varscan2
- CYP4F2 | c.408C>T p.L136= | Silent (SNP) | VAF 54/136 reads (40%) | catalogued as COSV99171181; called by muse, mutect2, varscan2
- DAZL | c.744G>A p.V248= | Silent (SNP) | VAF 56/195 reads (29%) | catalogued as COSV99167557; called by muse, mutect2, varscan2
- DDHD1 | c.888T>C p.Y296= (on ENST00000323669; = p.Y493= on NM_030637.3) | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV100080231; called by muse, mutect2, varscan2
- DDN | c.2085C>T p.F695= | Silent (SNP) | VAF 51/124 reads (41%) | catalogued as rs1162734057, COSV101373647; called by muse, mutect2, varscan2
- DDX31 | c.1545C>T p.V515= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV100140379; called by muse, mutect2, varscan2
- DGKH | c.1458G>A p.T486= | Silent (SNP) | VAF 59/148 reads (40%) | catalogued as rs774295145, COSV99819773; called by muse, mutect2, varscan2
- DICER1 | c.3654C>T p.S1218= | Silent (SNP) | VAF 63/180 reads (35%) | catalogued as COSV100602658; called by muse, mutect2, varscan2
- DLG4 | c.90C>T p.P30= (on ENST00000399506 / NM_001321075.3; = p.P73= on NM_001365.4) | Silent (SNP) | VAF 63/146 reads (43%) | catalogued as COSV100264088; called by muse, mutect2, varscan2
- DNAAF5 | c.627C>T p.I209= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as rs370516537, COSV52417862; called by muse, mutect2, varscan2
- DNAH8 | c.11109C>T p.I3703= | Silent (SNP) | VAF 41/66 reads (62%) | catalogued as COSV100547447; called by muse, mutect2, varscan2
- DNAH9 | c.6315G>A p.R2105= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV52334735; called by muse, mutect2
- DNMBP | c.2577G>A p.R859= | Silent (SNP) | VAF 57/144 reads (40%) | catalogued as COSV100144537; called by muse, mutect2, varscan2
- DOT1L | c.1494C>T p.F498= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV101288892; called by muse, mutect2, varscan2
- DRC3 | c.867G>A p.E289= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV100572834; called by muse, mutect2, varscan2
- DSPP | c.1377C>T p.S459= | Silent (SNP) | VAF 37/102 reads (36%) | catalogued as COSV99218175; called by muse, mutect2, varscan2
- ECEL1 | c.859C>T p.L287= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs1324461714, COSV100459113; called by muse, mutect2, varscan2
- EHMT1 | c.3300C>T p.P1100= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV101509737; called by muse, mutect2, varscan2
- EML4 | c.1978C>T p.L660= | Silent (SNP) | VAF 52/137 reads (38%) | catalogued as rs769058958, COSV100581513; called by muse, mutect2, varscan2
- EPPK1 | c.3864C>T p.F1288= | Silent (SNP) | VAF 48/161 reads (30%) | catalogued as rs782335306, COSV101599952, COSV73262238; called by muse, mutect2, varscan2
- ESS2 | c.588C>T p.L196= | Silent (SNP) | VAF 45/138 reads (33%) | catalogued as rs776917270, COSV99351325; called by muse, mutect2, varscan2
- F7 | c.558C>T p.S186= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as COSV100661125; called by muse, mutect2, varscan2
- FAM160B2 | c.1914C>T p.P638= | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as COSV99249334; called by muse, mutect2, varscan2
- FAM83C | c.1384C>T p.L462= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV100981754; called by muse, mutect2, varscan2
- FAT3 | c.7254C>T p.A2418= | Silent (SNP) | VAF 47/146 reads (32%) | catalogued as rs368946391, COSV53130681; called by muse, mutect2, varscan2
- FCF1 | c.519A>G p.G173= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV100356913; called by muse, mutect2, varscan2
- FNDC7 | c.1128T>C p.S376= | Silent (SNP) | VAF 94/235 reads (40%) | catalogued as COSV99601848; called by muse, mutect2, varscan2
- FOXJ2 | c.13C>T p.L5= | Silent (SNP) | VAF 69/187 reads (37%) | catalogued as COSV50824215; called by muse, mutect2, varscan2
- FREM1 | c.5124A>T p.I1708= | Silent (SNP) | VAF 19/26 reads (73%) | catalogued as COSV101085705; called by muse, mutect2, varscan2
- GALNS | c.138C>T p.L46= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs140588640, COSV99243589; called by muse, mutect2, varscan2
- GDF10 | c.918G>A p.L306= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs782219745; called by muse, mutect2, varscan2
- GLI3 | c.768C>T p.P256= | Silent (SNP) | VAF 58/177 reads (33%) | catalogued as rs745758384, COSV101230144; called by muse, mutect2, varscan2
- GRIN1 | c.1971G>A p.L657= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs1564363935, COSV100160825; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GSTCD | c.891C>T p.F297= (on ENST00000360505 / NM_001031720.3; = p.F210= on NM_024751.3) | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as COSV100853885; called by muse, mutect2, varscan2
- GTSF1L | c.429C>T p.I143= | Silent (SNP) | VAF 52/147 reads (35%) | catalogued as COSV100883964; called by muse, mutect2, varscan2
- GUCY2D | c.1578G>A p.G526= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs747095961, COSV99644172, COSV99644379; called by muse, mutect2, varscan2
- HMSD | c.366C>T p.F122= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs772541743, COSV68816777; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1149C>T p.F383= | Silent (SNP) | VAF 74/201 reads (37%) | catalogued as rs528087616, COSV54568441; called by muse, mutect2, varscan2
- IDO1 | c.1024C>T p.L342= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99503529; called by muse, mutect2, varscan2
- IFRD1 | c.1119C>T p.T373= | Silent (SNP) | VAF 45/138 reads (33%) | catalogued as COSV99134480; called by muse, mutect2, varscan2
- IGHV6-1 | c.24C>T p.F8= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as rs1555405882; called by muse, mutect2, varscan2
- IL23R | c.1140C>T p.F380= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV100724966; called by muse, mutect2, varscan2
- ITGAM | c.1092C>T p.P364= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV99793316; called by muse, mutect2, varscan2
- ITGB4 | c.3768C>T p.C1256= | Silent (SNP) | VAF 46/113 reads (41%) | catalogued as rs1356750607, COSV99565022; called by muse, mutect2, varscan2
- KALRN | c.8751G>A p.V2917= (on ENST00000360013 / NM_001024660.4; = p.V1220= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV52249762; called by muse, mutect2, varscan2
- KCNA1 | c.862C>T p.L288= | Silent (SNP) | VAF 50/144 reads (35%) | catalogued as COSV101230406; called by muse, mutect2, varscan2
- KCNC1 | c.1080C>T p.A360= | Silent (SNP) | VAF 42/93 reads (45%) | catalogued as COSV99789845; called by muse, mutect2, varscan2
- KCNJ10 | c.366C>T p.S122= | Silent (SNP) | VAF 110/191 reads (58%) | catalogued as rs1471561944, COSV100927924; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNT2 | c.429A>G p.E143= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV99657444; called by muse, mutect2
- KCNV1 | c.426C>T p.I142= | Silent (SNP) | VAF 42/73 reads (58%) | catalogued as rs751592297, COSV99819531; called by muse, mutect2, varscan2
- KIAA1217 | c.2544C>T p.V848= | Silent (SNP) | VAF 43/111 reads (39%) | catalogued as COSV56819118; called by muse, mutect2, varscan2
- KIF21B | c.4620C>T p.I1540= (on ENST00000422435 / NM_001252100.2; = p.I1527= on NM_017596.4) | Silent (SNP) | VAF 48/171 reads (28%) | catalogued as COSV59759807; called by muse, mutect2, varscan2
- KIF2B | c.1293C>T p.I431= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV52135251; called by muse, mutect2, varscan2
- LCE1A | c.15G>A p.Q5= | Silent (SNP) | VAF 128/217 reads (59%) | catalogued as COSV100632164; called by muse, mutect2, varscan2
- LCN12 | c.132C>T p.F44= | Silent (SNP) | VAF 75/242 reads (31%) | catalogued as rs200874027, COSV65421642; called by muse, mutect2, varscan2
- LCT | c.2820G>A p.G940= | Silent (SNP) | VAF 48/122 reads (39%) | catalogued as COSV99928857; called by muse, mutect2, varscan2
- LGSN | c.1068C>T p.S356= | Silent (SNP) | VAF 75/126 reads (60%) | catalogued as COSV101040780; called by muse, mutect2, varscan2
- LMX1A | c.1005C>T p.F335= | Silent (SNP) | VAF 49/169 reads (29%) | catalogued as COSV99672119; called by muse, mutect2, varscan2
- LRRC37A3 | c.201C>T p.F67= | Silent (SNP) | VAF 23/204 reads (11%) | catalogued as rs749437947; called by muse, mutect2, varscan2
- LRRN2 | c.1167C>T p.F389= | Silent (SNP) | VAF 44/167 reads (26%) | catalogued as COSV100913011; called by muse, mutect2, varscan2
- LZTFL1 | c.447C>T p.L149= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as COSV56112225; called by muse, mutect2, varscan2
- MAGEB6 | c.27C>T p.L9= | Silent (SNP) | VAF 41/57 reads (72%) | catalogued as COSV100983896; called by muse, mutect2, varscan2
- MAGEE2 | c.669G>A p.R223= | Silent (SNP) | VAF 54/69 reads (78%) | catalogued as rs367730676, COSV64898027; called by muse, mutect2, varscan2
- MAP2 | c.4776A>G p.T1592= | Silent (SNP) | VAF 47/142 reads (33%) | catalogued as COSV99562069; called by muse, mutect2, varscan2
- MARCHF2 | c.315C>T p.Y105= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as COSV99294917; called by muse, mutect2, varscan2
- MARCHF4 | c.780C>T p.F260= | Silent (SNP) | VAF 81/185 reads (44%) | catalogued as rs139354980; called by muse, mutect2, varscan2
- MAU2 | c.1038C>T p.C346= | Silent (SNP) | VAF 63/177 reads (36%) | catalogued as COSV99449299; called by muse, mutect2, varscan2
- MEGF8 | c.2001C>T p.F667= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as rs778349119, COSV99239685; called by muse, mutect2, varscan2
- METTL14 | c.330A>T p.T110= | Silent (SNP) | VAF 42/140 reads (30%) | catalogued as COSV101183429; called by muse, mutect2, varscan2
- MIB1 | c.2553C>T p.L851= | Silent (SNP) | VAF 50/128 reads (39%) | catalogued as COSV99839631; called by muse, mutect2, varscan2
- MST1R | c.2139C>T p.T713= | Silent (SNP) | VAF 51/132 reads (39%) | catalogued as rs759047577, COSV99619959; called by muse, mutect2, varscan2
- MYCBPAP | c.1023C>T p.F341= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100088190; called by muse, mutect2, varscan2
- MYH11 | c.1299C>T p.F433= | Silent (SNP) | VAF 49/133 reads (37%) | catalogued as COSV100260539; called by muse, mutect2, varscan2
- MYH15 | c.2340G>A p.G780= | Silent (SNP) | VAF 35/95 reads (37%) | catalogued as COSV99844540; called by muse, mutect2, varscan2
- MYH2 | c.5385C>T p.T1795= | Silent (SNP) | VAF 73/192 reads (38%) | catalogued as rs1042321, COSV55445125, COSV99821173; called by muse, mutect2, varscan2
- MYH2 | c.228G>A p.Q76= | Silent (SNP) | VAF 91/280 reads (33%) | catalogued as COSV99821175; called by muse, mutect2, varscan2
- MYH3 | c.5739C>T p.I1913= | Silent (SNP) | VAF 52/125 reads (42%) | catalogued as rs1011279441, COSV56863640; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYH4 | c.5436G>A p.G1812= | Silent (SNP) | VAF 72/196 reads (37%) | catalogued as COSV55116331; called by muse, mutect2, varscan2
- MYLK2 | c.306G>A p.A102= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs764441706, COSV101044982; called by muse, mutect2, varscan2
- NAP1L3 | c.1386G>A p.L462= | Silent (SNP) | VAF 30/36 reads (83%) | catalogued as COSV100220503, COSV100220758; called by muse, mutect2, varscan2
- NCR3 | c.72C>T p.P24= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as rs1356265339, COSV99279238; called by muse, mutect2, varscan2
- NEXMIF | c.3024C>T p.S1008= | Silent (SNP) | VAF 29/42 reads (69%) | catalogued as COSV99282216; called by muse, mutect2, varscan2
- NID2 | c.2277G>A p.P759= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as rs747580497, COSV53496717, COSV99357429; called by muse, mutect2, varscan2
- NLRP10 | c.546C>T p.L182= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as rs768045821, COSV100149679; called by muse, mutect2, varscan2
- NLRP7 | c.1953G>A p.P651= | Silent (SNP) | VAF 44/128 reads (34%) | catalogued as rs370874996, COSV60171329; called by muse, mutect2, varscan2
- NOD2 | c.3018C>T p.A1006= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV100318959; called by muse, mutect2, varscan2
- NPIPB15 | c.780C>T p.S260= | Silent (SNP) | VAF 24/377 reads (6%) | catalogued as rs1166859080, COSV101466058; called by muse, mutect2
- NPY1R | c.150G>A p.V50= | Silent (SNP) | VAF 48/136 reads (35%) | catalogued as COSV99649125; called by muse, mutect2, varscan2
- OR10K1 | c.624C>T p.V208= | Silent (SNP) | VAF 141/258 reads (55%) | catalogued as COSV99194075; called by muse, mutect2, varscan2
- OR10T2 | c.354G>A p.V118= | Silent (SNP) | VAF 108/195 reads (55%) | catalogued as rs1268900928, COSV57781871; called by muse, mutect2, varscan2
- OR1J4 | c.501C>T p.S167= | Silent (SNP) | VAF 34/115 reads (30%) | catalogued as COSV61589720; called by muse, mutect2, varscan2
- OR2A12 | c.429G>A p.L143= | Silent (SNP) | VAF 81/200 reads (41%) | catalogued as COSV101283211; called by muse, mutect2, varscan2
- OR2A12 | c.531C>T p.F177= | Silent (SNP) | VAF 65/166 reads (39%) | catalogued as COSV101283212; called by muse, mutect2, varscan2
- OR2F1 | c.111G>A p.V37= | Silent (SNP) | VAF 138/336 reads (41%) | catalogued as COSV101231340; called by muse, mutect2, varscan2
- OR2L8 | c.775C>T p.L259= | Silent (SNP) | VAF 86/284 reads (30%) | catalogued as COSV100594357, COSV61727736; called by muse, varscan2
- OR2L8 | c.790C>T p.L264= | Silent (SNP) | VAF 138/252 reads (55%) | catalogued as COSV100594360, COSV61726991; called by muse, varscan2
- OR2T10 | c.654C>T p.Y218= | Silent (SNP) | VAF 74/138 reads (54%) | catalogued as COSV100393847, COSV57897314; called by muse, mutect2, varscan2
- OR4C15 | c.99C>T p.F33= | Silent (SNP) | VAF 66/197 reads (34%) | catalogued as rs760696526, COSV58951213, COSV58956039; called by muse, mutect2, varscan2
- OR4K5 | c.870G>A p.R290= | Silent (SNP) | VAF 70/210 reads (33%) | catalogued as COSV60002477; called by muse, mutect2, varscan2
- OR4L1 | c.435G>A p.A145= | Silent (SNP) | VAF 80/200 reads (40%) | catalogued as rs374852761, COSV59851227; called by muse, mutect2, varscan2
- OR51A2 | c.261C>T p.F87= | Silent (SNP) | VAF 75/103 reads (73%) | catalogued as COSV66748154; called by muse, mutect2, varscan2
- OR51V1 | c.522C>T p.F174= | Silent (SNP) | VAF 47/119 reads (39%) | catalogued as COSV100343559; called by muse, mutect2, varscan2
- OR52K2 | c.489C>T p.F163= | Silent (SNP) | VAF 67/165 reads (41%) | catalogued as COSV57834806; called by muse, mutect2, varscan2
- OR56B4 | c.57C>T p.I19= | Silent (SNP) | VAF 44/105 reads (42%) | catalogued as COSV100337602; called by muse, mutect2, varscan2
- OR5M8 | c.252C>T p.F84= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as COSV59117228, COSV59117747; called by muse, mutect2, varscan2
- OR6C65 | c.525C>T p.F175= | Silent (SNP) | VAF 138/356 reads (39%) | catalogued as rs1178352837, COSV65568655; called by muse, mutect2, varscan2
- OR6F1 | c.738C>G p.T246= | Silent (SNP) | VAF 134/228 reads (59%) | catalogued as COSV57467135, COSV57467283; called by muse, mutect2, varscan2
- OR8B12 | c.540C>T p.I180= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV100172975; called by muse, mutect2, varscan2
- PBX4 | c.228C>T p.P76= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as COSV99232524; called by muse, mutect2, varscan2
- PCDH15 | c.2202C>T p.A734= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as rs201636125, COSV100229117; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHA11 | c.1300C>T p.L434= | Silent (SNP) | VAF 141/337 reads (42%) | catalogued as COSV56558912; called by muse, mutect2, varscan2
- PDYN | c.171G>A p.E57= | Silent (SNP) | VAF 45/109 reads (41%) | catalogued as rs868423862, COSV99453442; called by muse, mutect2, varscan2
- PHF21B | c.672C>T p.P224= | Silent (SNP) | VAF 55/127 reads (43%) | catalogued as rs1569224251, COSV100504137; called by muse, mutect2, varscan2
- PLEKHG5 | c.1800G>A p.K600= (on ENST00000400915 / NM_001042663.3; = p.K563= on NM_020631.6) | Silent (SNP) | VAF 53/91 reads (58%) | catalogued as COSV100557229; called by muse, mutect2, varscan2
- PLXNB1 | c.3816C>T p.V1272= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as rs748948370, COSV56494021; called by muse, mutect2, varscan2
- POU6F2 | c.432G>A p.A144= | Silent (SNP) | VAF 37/111 reads (33%) | catalogued as rs143731302; called by muse, mutect2, varscan2
- PPM1D | c.1737C>T p.T579= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as COSV100011253; called by muse, mutect2, varscan2
- PPP1R9B | c.1474T>C p.L492= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV100380821; called by muse, mutect2, varscan2
- PRAME | c.1290C>T p.L430= | Silent (SNP) | VAF 68/168 reads (40%) | catalogued as rs753291223, COSV101287285; called by muse, mutect2
- PRAMEF18 | c.828G>A p.R276= | Silent (SNP) | VAF 74/445 reads (17%) | called by muse, mutect2, varscan2
- PRL | c.555G>A p.Q185= | Silent (SNP) | VAF 29/119 reads (24%) | catalogued as COSV100123274; called by muse, mutect2, varscan2
- PTPRH | c.1899G>A p.E633= | Silent (SNP) | VAF 53/133 reads (40%) | catalogued as rs373455768; called by muse, mutect2, varscan2
- RASGRF1 | c.1008C>T p.F336= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs762945870, COSV69177966; called by muse, mutect2, varscan2
- RASGRF1 | c.513C>T p.I171= | Silent (SNP) | VAF 79/179 reads (44%) | catalogued as COSV69178321; called by muse, mutect2, varscan2
- RASGRF2 | c.162C>T p.F54= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV99430846; called by muse, mutect2, varscan2
- REG3G | c.216C>T p.P72= | Silent (SNP) | VAF 61/231 reads (26%) | catalogued as COSV99709779; called by muse, mutect2, varscan2
- ROS1 | c.6798G>A p.T2266= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as rs367838842; called by muse, mutect2, varscan2
- RP1 | c.2304C>T p.S768= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as CD992278, COSV55111389; called by muse, mutect2, varscan2
- RP1 | c.5838C>T p.F1946= | Silent (SNP) | VAF 45/124 reads (36%) | catalogued as COSV55117452; called by muse, mutect2, varscan2
- RYR2 | c.5253C>T p.I1751= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs745565940, COSV100773285; ClinVar: likely benign; called by muse, mutect2, varscan2
- SAMD7 | c.258G>A p.R86= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV59418952, COSV59421970; called by muse, mutect2, varscan2
- SASH3 | c.546C>T p.T182= | Silent (SNP) | VAF 112/156 reads (72%) | catalogued as rs773324212, COSV63555976; called by muse, mutect2, varscan2
- SATB1 | c.921C>T p.L307= | Silent (SNP) | VAF 52/143 reads (36%) | catalogued as rs752846934, COSV58669645; called by muse, mutect2, varscan2
- SCN10A | c.801C>T p.L267= | Silent (SNP) | VAF 43/90 reads (48%) | catalogued as rs149892218; called by muse, mutect2, varscan2
- SCN10A | c.576G>A p.L192= | Silent (SNP) | VAF 57/182 reads (31%) | catalogued as rs772562566, COSV101479582; called by muse, mutect2, varscan2
- SCN2A | c.1965C>A p.S655= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV99333955; called by muse, mutect2, varscan2
- SCYL2 | c.1503C>T p.S501= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV62569659; called by muse, mutect2, varscan2
- SDK2 | c.5499C>T p.I1833= | Silent (SNP) | VAF 95/214 reads (44%) | catalogued as COSV101168932; called by muse, mutect2, varscan2
- SETBP1 | c.453G>A p.T151= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as rs760574580, COSV56327761; called by muse, mutect2, varscan2
- SHOX2 | c.399A>G p.E133= (on ENST00000441443 / NM_006884.3; = p.E157= on NM_003030.4) | Silent (SNP) | VAF 63/169 reads (37%) | catalogued as COSV101273856; called by muse, mutect2, varscan2
- SLC22A8 | c.1533C>T p.S511= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV100268159; called by muse, mutect2, varscan2
- SLC25A10 | c.261C>T p.D87= | Silent (SNP) | VAF 165/452 reads (37%) | catalogued as COSV100519147; called by muse, mutect2, varscan2
- SLC39A4 | c.1767C>T p.I589= (on ENST00000301305 / NM_001374839.1; = p.I564= on NM_017767.3) | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as rs1312566759, COSV99433888; called by muse, mutect2, varscan2
- SLC6A4 | c.462C>T p.I154= | Silent (SNP) | VAF 79/206 reads (38%) | catalogued as COSV55565900; called by muse, mutect2, varscan2
- SLC7A11 | c.1173C>T p.F391= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV99763585; called by muse, mutect2, varscan2
- SLCO6A1 | c.1110G>A p.K370= | Silent (SNP) | VAF 42/148 reads (28%) | catalogued as COSV101134113, COSV101135170; called by muse, mutect2, varscan2
- SNRNP27 | c.105G>A p.E35= | Silent (SNP) | VAF 63/165 reads (38%) | catalogued as COSV99732294; called by muse, mutect2, varscan2
- SOHLH1 | c.957C>T p.G319= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs1161980185, COSV53684646; called by muse, mutect2, varscan2
70 further variants in this file (0 protein-altering or splice-affecting, 51 silent, 19 other) are not listed here.
